Gene-level copy-number profile of tumor specimen AP-AGZG-87 from APOLLO case AP-AGZG, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Lepidic adenocarcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2.
Specimen AP-AGZG-87: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ba08a760-5788-4107-b1ad-8faad59cbf48.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-AGZG-5N (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/fe5d8a11-a1cc-4c2d-8a17-2b39d4ffb3cb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 203; copy number 1: 22,982; copy number 2: 31,755; copy number 3: 3,539; copy number 4: 101; copy number 5: 23; copy number 6: 11; copy number 7: 3; copy number 8: 60; copy number 9: 134; copy number 10: 92; copy number 12: 7.

Homozygous deletions (total copy number 0; autosomes only): 203 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,203,171–49,589,529, 19 genes: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr7:67,691,058–69,430,923, 17 genes: AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3, AC004910.1, RNA5SP231, AC104688.1, RNU6-832P, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P.
- chr7:71,132,144–72,447,151, 8 genes: GALNT17, MIR3914-1, MIR3914-2, RN7SKP75, CALN1, RNA5SP232, AC005011.1, ABCF2P2.
- chr7:157,466,231–158,623,449, 17 genes: AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1.
- chr10:38,601,418–38,783,108, 8 genes: ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr10:94,646,364–95,168,425, 14 genes: CTBP2P2, CYP2C18, AL583836.1, CYP2C19, MTND4P19, CYP2C58P, RPL7AP52, CYP2C9, MTND4P20, CYP2C59P, CYP2C60P, AL359672.1, CYP2C8, AL157834.4.
- chr12:38,078,529–38,087,392, 2 genes: AK6P2, CLUHP8.
- chr12:113,358,566–115,639,734, 37 genes (within-gene range 0–1): PLBD2, SDS, SDSL, LHX5, LHX5-AS1, LINC01234, DYNLL1P4, RBM19, AC009731.1, AC073863.1, AC010183.1, AC010183.2, HAUS8P1, GLULP5, LINC02459, TBX5, TBX5-AS1, RN7SKP216, AC069240.1, OSTF1P1, AC010177.1, Y_RNA, TBX3, AC026765.3, AC026765.4, AC026765.1, AC026765.2, AC009804.1, AC008125.1, AC078880.1, AC078880.3, AC078880.4, AC078880.5, AC078880.2, AC009803.2, AC009803.1, UBA52P7.
- chr12:117,208,142–117,968,990, 5 genes (within-gene range 0–1): NOS1, ELOCP32, AC073864.1, KSR2, AC084291.1.
- chr14:105,583,731–105,673,314, 9 genes (within-gene range 0–1): IGHA2, IGHE, IGHG4, MIR8071-1, IGHG2, MIR8071-2, COPDA1, IGHGP, ELK2AP.
- chr14:105,721,794–105,722,527, 1 gene (within-gene range 0–1): IGHEP1.
- chr14:105,785,505–105,845,678, 2 genes (within-gene range 0–1): ATP6V1G1P1, IGHD.
- chr14:105,857,513–105,857,572, 1 gene (within-gene range 0–1): MIR4539.
- chr14:105,858,165–105,945,389, 42 genes (within-gene range 0–1): MIR4538, MIR4537, IGHJ6, IGHJ3P, IGHJ5, IGHJ4, IGHJ3, IGHJ2P, IGHJ2, IGHJ1, IGHD7-27, IGHJ1P, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1.
- chr22:47,115,838–49,266,080, 20 genes (within-gene range 0–1): FP325331.1, Z83836.1, Z82186.1, LINC01644, LINC00898, AL117329.1, AL117329.2, FP325330.3, FP325330.1, FP325330.2, BX284656.2, BX284656.1, MIR3201, Z82249.1, TAFA5, Z84468.1, MIR4535, LINC01310, RPL35P8, Z82202.1.
- chr22:49,500,568–49,501,585, 1 gene (within-gene range 0–1): AL008636.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 330 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:892,884–8,898,052, 143 genes, copy number 6–12 (broad region; genes not listed).
- chr5:9,035,033–9,546,075, 1 gene, copy number 10 (within-gene range 4–10): SEMA5A.
- chr5:9,363,275–15,266,541, 84 genes, copy number 8–10 (broad region; genes not listed).
- chr5:15,500,180–16,440,081, 9 genes, copy number 5 (within-gene range 2–5): FBXL7, CTD-2350J17.1, MIR887, RNA5SP178, MARCHF11, MARCHF11-AS1, AC092335.1, NACAP6, LINC02150.
- chr5:18,049,232–19,234,487, 12 genes, copy number 5–8: RPL36AP21, SNORD81, RN7SL58P, LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15.
- chr12:57,431,116–60,419,293, 75 genes, copy number 7–9 (broad region; genes not listed).
- chr12:78,326,680–78,808,995, 6 genes, copy number 5: LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2.

Autosomal genes at a single copy (total copy number 1): 20,638. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
